Somatic mutation profile of tumor specimen TCGA-HC-A8D1-01A (aliquot TCGA-HC-A8D1-01A-11D-A364-08) from TCGA case TCGA-HC-A8D1, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.8 years (25,137 days).
Specimen TCGA-HC-A8D1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b9c17f4-6989-444e-ab31-52fc12d924c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A8D1-10A (Blood Derived Normal), aliquot TCGA-HC-A8D1-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2140f32d-fe40-45e4-b32e-8a148c16b312

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLPTM1 | c.1480A>G p.S494G | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100493700; called by muse, mutect2, varscan2
- DHX29 | c.3760G>A p.A1254T | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.801); catalogued as COSV99287140; called by muse, mutect2
- GAL3ST1 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs749883972, COSV58891911; called by muse, mutect2, varscan2
- H2BC14 | c.239G>C p.R80P | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as rs757308721, COSV100297538, COSV60797646; called by muse, mutect2, varscan2
- HOXD8 | c.863T>G p.L288R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.015); catalogued as COSV100497047; called by muse, mutect2, varscan2
- ITGA9 | c.2629A>G p.I877V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.241); catalogued as rs1025966217, COSV99292167; called by muse, mutect2, varscan2
- NYNRIN | c.3277G>A p.A1093T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.105); catalogued as rs777933278, COSV66841162; called by muse, mutect2, varscan2
- PASD1 | c.1751A>G p.Q584R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV100949222; called by muse, mutect2, varscan2
- RAG1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as rs778391388, COSV55024800; called by muse, mutect2, varscan2
- SEL1L2 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99532924, COSV99533314; called by muse, mutect2, varscan2
- TRIM15 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as COSV64990240; called by muse, mutect2, varscan2
- TRIM8 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.64); catalogued as COSV100193160; called by muse, mutect2, varscan2
- ZBTB7B | c.1328A>G p.D443G (on ENST00000292176; = p.D477G on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99421014; called by muse, mutect2, varscan2
- FASN | c.2120del p.P707Hfs*34 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- ITGA8 | c.1698C>A p.R566= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV65225373, COSV65238466; called by muse, mutect2, varscan2
- NPC1L1 | c.1899G>T p.L633= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99204067; called by muse, mutect2, varscan2
- OR10A5 | c.549G>A p.P183= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs543931840, COSV55053137; called by muse, mutect2
- SIGLEC1 | c.3901C>T p.L1301= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99163657; called by mutect2, varscan2
- MAP2K7 | c.124+1780A>G | Intron (SNP) | VAF 26/140 reads (19%) | catalogued as rs562064143, COSV100142763; called by muse, mutect2, varscan2
